Somatic mutation profile of tumor specimen C3L-02214-01 (aliquot CPT0127920006) from CPTAC case C3L-02214, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 33.4 years (12,197 days).
Specimen C3L-02214-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e955fea7-12d4-407a-9a28-f8d983a7d4b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02214-31 (Blood Derived Normal), aliquot CPT0126590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/318a55d2-926c-4ac1-94da-e2334f521ee6

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.5821C>T p.P1941S | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54956621, COSV99796976; called by muse, mutect2, varscan2
- CCER2 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 47/507 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777939602; called by muse, mutect2
- GET4 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.03); catalogued as rs748554372; called by muse, mutect2, varscan2
- HYI | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1393829167; called by muse, mutect2
- PLXNA2 | c.2470G>A p.G824S | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1284264990; called by muse, mutect2, varscan2
- TNRC18 | c.6389C>T p.S2130F | Missense Mutation (SNP) | VAF 35/421 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1196293883, COSV60308945; called by muse, mutect2
- AGER | c.847_850del p.S283Lfs*3 | Frame Shift Del (DEL) | VAF 16/174 reads (9%) | called by mutect2, pindel
- LMX1A | c.61T>G p.F21V | Missense Mutation (SNP) | VAF 48/409 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYH4 | c.1419C>A p.F473L | Missense Mutation (SNP) | VAF 73/643 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNF222 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADGRE3 | c.1464C>T p.H488= | Silent (SNP) | VAF 32/291 reads (11%) | catalogued as rs371645604; called by muse, mutect2, varscan2
- DMBT1 | c.1516C>A p.R506= | Silent (SNP) | VAF 69/772 reads (9%) | called by muse, mutect2
- LRRC25 | c.78C>T p.T26= | Silent (SNP) | VAF 35/333 reads (11%) | called by muse, mutect2, varscan2
- GREM1 | c.-2+254C>T | Intron (SNP) | VAF 61/448 reads (14%) | called by muse, mutect2, varscan2
- PNPO | c.418-50T>C | Intron (SNP) | VAF 29/292 reads (10%) | called by muse, mutect2, varscan2
- TRPV3 | c.2278+14G>A | Intron (SNP) | VAF 28/261 reads (11%) | called by muse, mutect2, varscan2
- ZNF195 | c.226+4039C>A | Intron (SNP) | VAF 14/316 reads (4%) | called by muse, mutect2
